Somatic mutation profile of tumor specimen TCGA-2Z-A9JO-01A (aliquot TCGA-2Z-A9JO-01A-11D-A42J-10) from TCGA case TCGA-2Z-A9JO, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 56.0 years (20,466 days).
Specimen TCGA-2Z-A9JO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bb986af0-d6ad-43af-af37-db4044830726.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2Z-A9JO-10A (Blood Derived Normal), aliquot TCGA-2Z-A9JO-10A-01D-A42M-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b6e4a6a3-573b-4091-bb10-77ccfb1b9389

The open-access MAF lists 41 somatic variants for this specimen: 26 protein-altering or splice-affecting, 12 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 12, Frame Shift Del 3, Intron 2, Nonstop Mutation 1, Nonsense Mutation 1, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABRAXAS2 | c.1156C>G p.P386A | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.028); catalogued as rs765173289, COSV100044973; called by muse, mutect2, varscan2
- ADAM12 | c.1151C>A p.T384N | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100900643; called by muse, mutect2
- AKAP1 | c.736G>C p.G246R | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV100027998; called by muse, mutect2, varscan2
- ANK1 | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs368414600; called by muse, mutect2, varscan2
- ATG4C | c.824A>G p.Q275R | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT tolerated (0.83); PolyPhen benign (0.266); catalogued as COSV100508247; called by muse, mutect2, varscan2
- CCDC186 | c.632A>G p.K211R | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV100991022; called by muse, mutect2, varscan2
- FXYD1 | c.21C>G p.I7M | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV99544901; called by muse, mutect2, varscan2
- GUCD1 | c.385T>A p.C129S | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.051); catalogued as COSV101238124; called by muse, mutect2, varscan2
- LRRC1 | c.1160T>A p.L387Q | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100906405; called by muse, mutect2, varscan2
- MPP6 | c.448A>G p.N150D | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as COSV99757562; called by muse, mutect2, varscan2
- MTUS1 | c.1615G>A p.A539T | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.08); catalogued as rs1431528133, COSV100029509; called by muse, mutect2, varscan2
- NEB | c.14334C>A p.Y4778* | Nonsense Mutation (SNP) | VAF 4/74 reads (5%) | catalogued as COSV99423957; called by muse, mutect2
- NPAT | c.1948G>A p.E650K | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.009); catalogued as COSV99586078; called by muse, mutect2, varscan2
- NSD3 | c.1089A>T p.R363S | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.816); catalogued as COSV100388701; called by muse, varscan2
- PCED1B | c.555G>T p.K185N | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.55); PolyPhen benign (0.234); catalogued as COSV101423654, COSV71395184; called by muse, mutect2, varscan2
- PPP2R5E | c.1327C>T p.R443C | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100518654; called by muse, mutect2, varscan2
- PROM1 | c.1514T>A p.F505Y | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101477090; called by muse, mutect2, varscan2
- RALGAPA1 | c.4508C>T p.S1503F | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV99354987; called by muse, mutect2, varscan2
- SOX9 | c.380A>G p.Y127C | Missense Mutation (SNP) | VAF 57/161 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99818473; called by muse, mutect2, varscan2
- TK2 | c.531+1G>C p.X177_splice (on ENST00000299697; = p.X233_splice on NM_004614.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 19/54 reads (35%) | catalogued as COSV100228134; called by muse, mutect2, varscan2
- ZIM3 | c.721C>A p.H241N | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99518173; called by muse, mutect2
- ATP6V1E2 | c.674_*4del | Nonstop Mutation (DEL) | VAF 10/43 reads (23%) | called by mutect2, pindel, varscan2
- C2CD6 | c.125del p.H42Pfs*14 | Frame Shift Del (DEL) | VAF 39/141 reads (28%) | called by mutect2, pindel, varscan2
- MAPRE3 | c.373_377del p.N125Sfs*14 | Frame Shift Del (DEL) | VAF 30/106 reads (28%) | called by mutect2, pindel, varscan2
- MYO7B | c.5395del p.I1799Sfs*65 | Frame Shift Del (DEL) | VAF 35/161 reads (22%) | called by mutect2, pindel, varscan2
- RSPH10B2 | c.485G>T p.G162V | Missense Mutation (SNP) | VAF 31/206 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- ACE2 | c.1221C>T p.I407= | Silent (SNP) | VAF 43/123 reads (35%) | catalogued as COSV99382845; called by muse, mutect2, varscan2
- EEA1 | c.3900T>C p.L1300= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as COSV100467764; called by muse, mutect2, varscan2
- FAM160A2 | c.2265C>T p.N755= (on ENST00000449352 / NM_001098794.2; = p.N769= on NM_032127.4) | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV99792132, COSV99792448; called by muse, mutect2, varscan2
- FLRT2 | c.726G>T p.L242= | Silent (SNP) | VAF 3/49 reads (6%) | catalogued as COSV58142216, COSV58151200; called by muse, mutect2
- FMO2 | c.159T>C p.S53= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as COSV99269159; called by muse, mutect2, varscan2
- LANCL3 | c.372C>T p.G124= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as COSV101065660; called by muse, mutect2, varscan2
- PATJ | c.1008C>G p.P336= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV100334391; called by muse, mutect2
- PDILT | c.1465C>T p.L489= | Silent (SNP) | VAF 17/79 reads (22%) | catalogued as COSV100199280; called by muse, mutect2, varscan2
- RCCD1 | c.393T>A p.A131= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as COSV101263218; called by muse, mutect2, varscan2
- SUPT6H | c.1101A>C p.R367= | Silent (SNP) | VAF 34/107 reads (32%) | catalogued as COSV100112469; called by muse, mutect2, varscan2
- TBRG4 | c.126A>G p.S42= | Silent (SNP) | VAF 21/92 reads (23%) | catalogued as COSV99345443; called by muse, mutect2, varscan2
- ZAP70 | c.1581C>T p.V527= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as COSV99385597; called by muse, mutect2, varscan2
- CACNB2 | c.213+110319C>T | Intron (SNP) | VAF 12/56 reads (21%) | catalogued as rs1163058545, COSV99994388; called by muse, mutect2
- CPLANE1 | c.*5454T>G | 3'UTR (SNP) | VAF 39/125 reads (31%) | catalogued as COSV99950750; called by muse, mutect2, varscan2
- PRR12 | c.52-441A>C | Intron (SNP) | VAF 14/48 reads (29%) | catalogued as COSV101330689; called by muse, mutect2, varscan2
